Somatic mutation profile of tumor specimen TARGET-10-PARERS-09A (aliquot TARGET-10-PARERS-09A-01D) from TARGET case TARGET-10-PARERS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,458 days).
Specimen TARGET-10-PARERS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1d64ab0-9b7b-4299-8169-105a21b57043.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARERS-10A (Blood Derived Normal), aliquot TARGET-10-PARERS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9339afea-5be4-4327-8911-26840e85b6d0

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, RNA 2, Silent 2, Intron 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 15/61 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.12367G>T p.A4123S | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV71291478; called by muse, mutect2, varscan2
- ADCY5 | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1470579590; called by muse, mutect2, varscan2
- DIP2A | c.3778G>A p.A1260T | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs368502145; called by muse, mutect2, varscan2
- FRS3 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1490882300; called by muse, mutect2, varscan2
- HCN1 | c.2144G>A p.R715Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.992); catalogued as rs1242068538, COSV100302034, COSV57497988; called by muse, mutect2, varscan2
- MAGEA12 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 88/272 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as rs1556833497, COSV63294552, COSV63294755; called by muse, mutect2, varscan2
- NKX2-3 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs762172308; called by muse, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XBP1 | c.454-2A>G p.X152_splice | Splice Site (SNP) | VAF 10/47 reads (21%) | catalogued as COSV53274455; called by muse, mutect2, varscan2
- NLRP13 | c.2053A>G p.N685D | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SETD2 | c.6509G>A p.G2170D | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTDP1 | c.414C>T p.N138= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as rs755319299, COSV50002185; called by muse, mutect2, varscan2
- FUCA2 | c.1227C>T p.F409= | Silent (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2, varscan2
- AC097518.1 | n.66C>T | RNA (SNP) | VAF 25/103 reads (24%) | catalogued as rs1485986653; called by muse, mutect2, varscan2
- PTPN21 | c.*99C>T | 3'UTR (SNP) | VAF 17/58 reads (29%) | catalogued as rs532268528; called by muse, mutect2, varscan2
- SCLY | c.802-209C>T | Intron (SNP) | VAF 14/42 reads (33%) | catalogued as rs967918831, COSV54542218; called by muse, mutect2
- SSPOP | n.6033G>A | RNA (SNP) | VAF 11/52 reads (21%) | catalogued as rs200695724; called by muse, mutect2, varscan2
